Somatic mutation profile of tumor specimen TCGA-13-0755-01A (aliquot TCGA-13-0755-01A-01W-0371-08) from TCGA case TCGA-13-0755, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 75.1 years (27,438 days).
Specimen TCGA-13-0755-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1563af8d-1c0e-468d-8b80-8e19ddc57aad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0755-10A (Blood Derived Normal), aliquot TCGA-13-0755-10A-01W-0371-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c79640d-3995-4cf6-aa30-035e5e4ed16c

The open-access MAF lists 115 somatic variants for this specimen: 91 protein-altering or splice-affecting, 23 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 23, Nonsense Mutation 6, Splice Region 4, Frame Shift Del 3, Splice Site 3, In Frame Del 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 100/134 reads (75%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, varscan2
- ABT1 | c.692G>C p.R231P | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV51292271; called by muse, mutect2
- ANXA2 | c.367A>C p.T123P | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60317361; called by muse, mutect2, varscan2
- ARID2 | c.3496G>C p.G1166R | Missense Mutation (SNP) | VAF 67/188 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.219); catalogued as COSV57607308; called by muse, mutect2, varscan2
- ATP13A3 | c.2320G>T p.A774S | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); catalogued as COSV55465994; called by muse, mutect2, varscan2
- AVPR1B | c.895del p.S299Vfs*82 | Frame Shift Del (DEL) | VAF 11/21 reads (52%) | catalogued as COSV65638276; called by pindel, varscan2
- B4GALNT2 | c.1598C>A p.A533D | Missense Mutation (SNP) | VAF 77/90 reads (86%) | SIFT tolerated (0.4); PolyPhen benign (0.115); catalogued as COSV55926840; called by muse, mutect2
- BARHL2 | c.912C>G p.Y304* | Nonsense Mutation (SNP) | VAF 14/46 reads (30%) | catalogued as rs774851934, COSV64981524; called by muse, mutect2, varscan2
- BAZ2B | c.3687T>A p.S1229R | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV54276038; called by muse, mutect2
- C2CD6 | c.865C>A p.P289T | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53796483; called by muse, mutect2, varscan2
- CCDC32 | c.205G>C p.A69P | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.976); catalogued as COSV63635107; called by muse, mutect2, varscan2
- CCDC85A | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs541266691, COSV68152443; called by muse, mutect2, varscan2
- CD34 | c.951G>C p.W317C | Missense Mutation (SNP) | VAF 483/635 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60413759; called by muse, mutect2, varscan2
- CERS4 | c.846C>A p.T282= | Splice Region (SNP) | VAF 22/125 reads (18%) | catalogued as COSV52167973; called by muse, mutect2, varscan2
- CHD6 | c.3865G>A p.V1289M | Missense Mutation (SNP) | VAF 89/180 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV58558688; called by muse, mutect2, varscan2
- DOCK8 | c.2074A>T p.K692* | Nonsense Mutation (SNP) | VAF 310/592 reads (52%) | catalogued as COSV66621131; called by muse, mutect2, varscan2
- DUSP9 | c.976A>T p.N326Y | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61438127; called by muse, mutect2, varscan2
- EIF4EBP3 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1561853589, COSV51850839; called by muse, mutect2, varscan2
- FAM118B | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 19/603 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100796862; called by muse, mutect2
- FBLN1 | c.149G>A p.C50Y | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53049246; called by muse, mutect2, varscan2
- FEN1 | c.953A>T p.E318V | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV57251004; called by muse, mutect2, varscan2
- FLG | c.10449A>C p.R3483S | Missense Mutation (SNP) | VAF 195/487 reads (40%) | SIFT tolerated (1); PolyPhen probably damaging (0.992); catalogued as rs763378811, COSV64243457; called by muse, mutect2, varscan2
- GANAB | c.141C>T p.C47= | Splice Region (SNP) | VAF 40/115 reads (35%) | catalogued as COSV60465963; called by muse, mutect2, varscan2
- GFRA1 | c.677G>T p.R226L | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62603981, COSV62607405; called by muse, mutect2, varscan2
- GLIS2 | c.577C>G p.H193D | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99267788; called by muse, mutect2
- GRIN2A | c.1595G>A p.G532E | Missense Mutation (SNP) | VAF 318/890 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV58031099; called by muse, mutect2, varscan2
- GRPEL2 | c.139G>C p.E47Q | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.892); catalogued as COSV61387756; called by muse, mutect2, varscan2
- GSS | c.190C>G p.Q64E | Missense Mutation (SNP) | VAF 55/140 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.609); catalogued as COSV53813336; called by muse, mutect2, varscan2
- H3C1 | c.60G>T p.Q20H | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV55119799; called by muse, mutect2, varscan2
- HLCS | c.248G>A p.S83N | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs761147008, COSV60794885; called by muse, mutect2, varscan2
- KIF16B | c.2687A>T p.K896M | Missense Mutation (SNP) | VAF 24/854 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.642); catalogued as COSV100734831, COSV104418797; called by muse, mutect2
- KIF4B | c.847G>T p.G283C | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV70530062; called by muse, mutect2, varscan2
- KMT2C | c.1097A>C p.Y366S | Missense Mutation (SNP) | VAF 154/1552 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51455595; called by muse, varscan2
- KRI1 | c.982A>G p.R328G | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1568422668, COSV57265032; called by muse, mutect2, varscan2
- LSR | c.814C>G p.L272V (on ENST00000361790; = p.L253V on NM_015925.6) | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV100670621; called by muse, mutect2, varscan2
- LTF | c.1357+1G>C p.X453_splice | Splice Site (SNP) | VAF 54/134 reads (40%) | catalogued as COSV99211023; called by muse, mutect2, varscan2
- MAML3 | c.3085C>T p.Q1029* | Nonsense Mutation (SNP) | VAF 6/11 reads (55%) | catalogued as COSV101558512; called by muse, mutect2, varscan2
- MBNL1 | c.83C>G p.S28* | Nonsense Mutation (SNP) | VAF 95/131 reads (73%) | catalogued as COSV56830877; called by muse, mutect2, varscan2
- MEGF10 | c.1591-2A>T p.X531_splice | Splice Site (SNP) | VAF 13/55 reads (24%) | catalogued as COSV57251574; called by muse, mutect2, varscan2
- MELK | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 401/1127 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV53199898; called by muse, mutect2, varscan2
- MPP1 | c.249A>T p.G83= | Splice Region (SNP) | VAF 74/272 reads (27%) | catalogued as COSV65728392; called by muse, mutect2
- MUC16 | c.41586C>A p.C13862* | Nonsense Mutation (SNP) | VAF 96/371 reads (26%) | catalogued as COSV66693618, COSV66693625; called by muse, mutect2, varscan2
- MYO5C | c.202G>A p.G68S | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs971747708, COSV55908130; called by muse, mutect2, varscan2
- NKRF | c.1130G>C p.R377P | Missense Mutation (SNP) | VAF 53/136 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.835); catalogued as COSV100441847, COSV58662541; called by muse, mutect2, varscan2
- NT5E | c.898G>A p.V300I | Missense Mutation (SNP) | VAF 141/382 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.691); catalogued as rs148199616; called by muse, mutect2, varscan2
- NXPH2 | c.322T>A p.F108I | Missense Mutation (SNP) | VAF 64/136 reads (47%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.974); catalogued as COSV55644079; called by muse, mutect2, varscan2
- NXPH2 | c.60T>A p.C20* | Nonsense Mutation (SNP) | VAF 108/267 reads (40%) | catalogued as COSV55644088; called by muse, mutect2, varscan2
- OR12D3 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 64/172 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.057); catalogued as COSV65828605; called by muse, mutect2, varscan2
- OTOP1 | c.1109G>A p.R370Q | Missense Mutation (SNP) | VAF 33/54 reads (61%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as rs374014211, COSV56397272; called by muse, mutect2, varscan2
- PAF1 | c.351C>A p.S117R | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.736); catalogued as COSV99655997; called by muse, mutect2
- PCDHAC1 | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs782761361, COSV99168095, COSV99169412; called by muse, mutect2, varscan2
- PCDHB12 | c.272A>T p.D91V | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99507732; called by muse, mutect2, varscan2
- PCDHB16 | c.2116C>T p.L706F | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.125); catalogued as COSV99502707; called by muse, mutect2, varscan2
- PDE6C | c.267C>A p.H89Q | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV101008841; called by muse, mutect2, varscan2
- PIH1D2 | c.920C>T p.T307M | Missense Mutation (SNP) | VAF 100/282 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.514); catalogued as rs782681479, COSV54771554; called by muse, mutect2, varscan2
- PKP4 | c.2227G>A p.V743M | Missense Mutation (SNP) | VAF 55/140 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.135); catalogued as rs374838936; called by muse, mutect2, varscan2
- PLA2G15 | c.986A>G p.H329R | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54723194, COSV99547344; called by muse, mutect2, varscan2
- PROM1 | c.816C>A p.N272K | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT tolerated (0.09); PolyPhen benign (0.192); catalogued as COSV71699592; called by muse, mutect2, varscan2
- RAD54L2 | c.2041A>C p.S681R | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV56579479; called by muse, mutect2, varscan2
- RDH5 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV57676620; called by muse, mutect2, varscan2
- ROBO4 | c.1484C>A p.A495D | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.374); catalogued as COSV60625313, COSV60628192; called by muse, mutect2, varscan2
- SEC14L3 | c.903C>G p.C301W | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53179965, COSV99307009; called by muse, varscan2
- SEC24B | c.317C>A p.T106K | Missense Mutation (SNP) | VAF 11/251 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV99494207; called by muse, mutect2
- SPATA31A3 | c.2051G>A p.R684K | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.64); catalogued as rs1411226363; called by muse, mutect2, varscan2
- SPOCD1 | c.2084T>G p.M695R | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57097301; called by muse, mutect2, varscan2
- SPTB | c.5528G>A p.R1843Q | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs534004149, COSV67632802; called by muse, mutect2, varscan2
- STK31 | c.548C>G p.S183C | Missense Mutation (SNP) | VAF 131/288 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV63457257; called by muse, mutect2, varscan2
- TBCE | c.950G>A p.R317K (on ENST00000366601; = p.R380K on NM_003193.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/284 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as rs1393991210, COSV100783237; called by muse, mutect2
- TGM6 | c.1309A>G p.I437V | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV52481145; called by muse, mutect2, varscan2
- THSD1 | c.373G>T p.V125L | Missense Mutation (SNP) | VAF 44/66 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV51629444; called by muse, mutect2, varscan2
- TMEM186 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 54/191 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs777643180, COSV51632412; called by muse, mutect2, varscan2
- TOPORS | c.382G>A p.V128I | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0.031); catalogued as COSV62117313; called by muse, mutect2, varscan2
- TTN | c.53843C>G p.T17948R (on ENST00000591111; = p.T10524R on NM_003319.4) | Missense Mutation (SNP) | VAF 75/164 reads (46%) | PolyPhen benign (0.121); catalogued as COSV60149445; called by muse, mutect2, varscan2
- TTN | c.11913G>T p.E3971D (on ENST00000591111; = p.E3925D on NM_003319.4) | Missense Mutation (SNP) | VAF 60/124 reads (48%) | catalogued as COSV60149477; called by muse, mutect2, varscan2
- TXNIP | c.497A>G p.K166R | Missense Mutation (SNP) | VAF 604/1231 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs782295244, COSV65220711; called by muse, mutect2, varscan2
- UBTF | c.1697A>C p.E566A | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as COSV100256110; called by muse, mutect2, varscan2
- UPP1 | c.573G>C p.L191F | Missense Mutation (SNP) | VAF 20/352 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.013); catalogued as COSV100080875; called by muse, mutect2
- USH2A | c.2534T>C p.L845P | Missense Mutation (SNP) | VAF 26/392 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV100241342; called by muse, mutect2
- USHBP1 | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.023); catalogued as rs762190493, COSV53104348; called by muse, mutect2, varscan2
- VSIG1 | c.265C>G p.R89G | Missense Mutation (SNP) | VAF 202/470 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54260043; called by muse, mutect2, varscan2
- WDR61 | c.544C>T p.L182F | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV51217090; called by muse, mutect2, varscan2
- YY1AP1 | c.941C>G p.T314S (on ENST00000295566 / NM_139118.2; = p.T257S on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 188/455 reads (41%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.791); catalogued as COSV55122340; called by muse, mutect2, varscan2
- ZNF200 | c.639G>T p.R213S | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV101205300; called by muse, mutect2, varscan2
- ZNF614 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs775740811, COSV54546899; called by muse, mutect2, varscan2
- ZNF70 | c.859A>G p.K287E | Missense Mutation (SNP) | VAF 145/324 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as COSV59533160; called by muse, mutect2, varscan2
- ASPRV1 | c.135del p.V46Sfs*14 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | called by mutect2, pindel, varscan2
- EGFLAM | c.1916_1931del p.I639Tfs*73 | Frame Shift Del (DEL) | VAF 152/440 reads (35%) | called by mutect2, pindel, varscan2
- EP300 | c.4173-1_4181del p.X1391_splice | Splice Site (DEL) | VAF 14/47 reads (30%) | called by mutect2, pindel, varscan2
- PTK7 | c.2700G>T p.Q900H | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.354); called by muse, mutect2
- TOP2A | c.609_613dup p.E205Gfs*36 | Frame Shift Ins (INS) | VAF 264/876 reads (30%) | called by pindel, varscan2
- YIPF5 | c.703_711del p.G235_Q237del | In Frame Del (DEL) | VAF 38/121 reads (31%) | called by mutect2, pindel, varscan2
- ABCA3 | c.4482C>T p.C1494= | Silent (SNP) | VAF 42/105 reads (40%) | catalogued as rs758260188, COSV57055613; called by muse, mutect2, varscan2
- ASAP1 | c.2994G>C p.L998= | Silent (SNP) | VAF 101/580 reads (17%) | catalogued as COSV63050457; called by muse, varscan2
- ATP5F1B | c.297G>C p.V99= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV56260668, COSV56261363; called by muse, mutect2, varscan2
- CA9 | c.195G>A p.L65= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as COSV65675945; called by muse, mutect2, varscan2
- CTTNBP2 | c.2163A>C p.G721= | Silent (SNP) | VAF 31/185 reads (17%) | catalogued as COSV50413590; called by muse, mutect2, varscan2
- DMAC2L | c.597G>A p.L199= | Silent (SNP) | VAF 52/119 reads (44%) | catalogued as COSV55412812, COSV55413707; called by muse, mutect2, varscan2
- FBXL14 | c.1002G>A p.T334= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV59336897; called by muse, mutect2, varscan2
- FCRL5 | c.1104T>G p.A368= | Silent (SNP) | VAF 186/465 reads (40%) | catalogued as COSV62516182; called by muse, mutect2, varscan2
- GPR158 | c.2250A>G p.L750= | Silent (SNP) | VAF 18/169 reads (11%) | catalogued as COSV100894209; called by muse, mutect2
- GRM3 | c.1923T>C p.C641= | Silent (SNP) | VAF 299/645 reads (46%) | catalogued as COSV64474136; called by muse, mutect2, varscan2
- HERC1 | c.8007A>C p.A2669= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV71248546; called by muse, mutect2, varscan2
- HMCN1 | c.4995T>G p.A1665= | Silent (SNP) | VAF 9/190 reads (5%) | called by muse, mutect2
- KIAA1109 | c.4380T>A p.P1460= | Silent (SNP) | VAF 48/133 reads (36%) | catalogued as COSV52679282; called by muse, mutect2, varscan2
- MAGT1 | c.252T>C p.H84= (on ENST00000618282 / NM_001367916.1; = p.H116= on NM_032121.5) | Silent (SNP) | VAF 520/1123 reads (46%) | catalogued as COSV100800415; called by muse, varscan2
- MAVS | c.561C>T p.L187= | Silent (SNP) | VAF 8/110 reads (7%) | called by muse, mutect2
- MYH15 | c.1188T>A p.A396= | Silent (SNP) | VAF 42/114 reads (37%) | catalogued as COSV56313174; called by muse, mutect2, varscan2
- RBM34 | c.153T>C p.G51= | Silent (SNP) | VAF 45/94 reads (48%) | catalogued as COSV64012956; called by muse, mutect2, varscan2
- RTN4R | c.339C>T p.S113= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs149052299; called by muse, varscan2
- SDSL | c.648G>C p.L216= | Silent (SNP) | VAF 17/505 reads (3%) | catalogued as COSV100615292; called by muse, mutect2
- SLC20A2 | c.93C>T p.N31= | Silent (SNP) | VAF 232/479 reads (48%) | catalogued as COSV60604533; called by muse, mutect2, varscan2
- TRMU | c.432T>G p.V144= | Silent (SNP) | VAF 42/87 reads (48%) | catalogued as COSV51990559; called by muse, mutect2, varscan2
- USP21 | c.666C>T p.F222= | Silent (SNP) | VAF 31/85 reads (36%) | catalogued as COSV57089542; called by muse, mutect2, varscan2
- ZNF585A | c.1554G>A p.G518= (on ENST00000292841 / NM_001288800.2; = p.G463= on NM_152655.3) | Silent (SNP) | VAF 106/320 reads (33%) | catalogued as COSV53064868; called by muse, mutect2, varscan2
- ZNF655 | c.*3_*23del | 3'UTR (DEL) | VAF 13/66 reads (20%) | called by mutect2, pindel
